Surgical pathology report (de-identified scan), TCGA case TCGA-44-6777, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6777-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Date Recd: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

Left upper lobe wedge resection

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer

GROSS DESCRIPTION

Received fresh, subsequently fixed in formalin, labeled "left upper lobe wedge resection". The specimen consists of a wedge of lung which is 78 gram. The specimen is 15 x 5.5 x 4 cm. and has a stapled margin of 15 cm. The pleura is violaceous smooth and glistening. There is a 1 x 1 cm. umbilication in the pleura. This focus is inked and the specimen is sectioned to show a 3.5 x 2.5 x 2.4 cm. pink tan tumor which shows fibrous stippling present. This is contiguous within the pleural umbilication. Representative tissue was submitted for tumor procurement. The tumor comes within 1.5 cm. of the sacral margin (inked black). The remainder of the cut surface of the lung is pink tan and spongy showing no other discrete gross lesions. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1-4 - Representative section of tumor including pleural umbilication and surgical stapled margin; 5 - representative of normal. RS-5 [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Primary tumor (pT): The tumor measures 3.5 cm. in maximum dimension and is limited to the lung parenchyma in the wedge specimen and invades into the pleura, pT2.
Margins of resection: Negative
Vascular invasion: Present
Regional lymph nodes (pN): pNX
Distant metastasis (pM): pMX
Other findings: A small piece of tissue from the tumor and normal tissue is submitted for the tumor bank.

4x1

DIAGNOSIS

Lung, left upper lobe wedge resection -
Invasive poorly-differentiated adenocarcinoma (see tumor characteristics in the lung template in the microscopic description).

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 1893d768-c624-42b6-8f2f-bca65431bb77 (TCGA-44-6777.600A1078-21F2-4267-9D3C-03F292FA6A32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).